Somatic mutation profile of tumor specimen TCGA-HC-7749-01A (aliquot TCGA-HC-7749-01A-11D-2114-08) from TCGA case TCGA-HC-7749, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.3 years (25,688 days).
Specimen TCGA-HC-7749-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53c54530-6704-4085-ad31-6ad63c133802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7749-10A (Blood Derived Normal), aliquot TCGA-HC-7749-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fca5208e-5440-4a87-8642-7890fab58b17

The open-access MAF lists 43 somatic variants for this specimen: 40 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Nonsense Mutation 4, Frame Shift Ins 2, Silent 2, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV51675968; called by muse, mutect2, varscan2
- ATXN3 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 38/125 reads (30%) | catalogued as COSV61497348; called by muse, mutect2, varscan2
- BPIFB3 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs751218546, COSV64957983; called by muse, mutect2, varscan2
- CAMK1 | c.365T>A p.I122N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56540050; called by muse, mutect2, varscan2
- CENPP | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV55335697; called by muse, mutect2, varscan2
- CNR1 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as rs199892728, COSV62990502; called by muse, mutect2, varscan2
- CSMD1 | c.10342G>T p.G3448* (on ENST00000520002; = p.G3447* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV59367891; called by muse, mutect2, varscan2
- CYTIP | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs758705411, COSV51634006; called by muse, mutect2
- DDX43 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV64837710; called by muse, mutect2, varscan2
- DNMT3L | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759685597, COSV54265660, COSV99533158; called by muse, varscan2
- GLI2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755043644, COSV58033928; ClinVar: uncertain significance; called by muse, mutect2
- IFI30 | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV55849786; called by muse, mutect2, varscan2
- IMPA1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56272615; called by muse, mutect2, varscan2
- IMPACT | c.166-1G>A p.X56_splice | Splice Site (SNP) | VAF 8/70 reads (11%) | catalogued as COSV52423041; called by muse, mutect2, varscan2
- IPMK | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV57266584; called by muse, mutect2, varscan2
- ITGB5 | c.1202G>C p.C401S | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56152129; called by muse, mutect2, varscan2
- KLHL6 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58068711; called by muse, mutect2
- KRTAP3-3 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV66956770; called by muse, mutect2
- KRTAP6-2 | c.6C>G p.C2W | Missense Mutation (SNP) | VAF 14/116 reads (12%) | PolyPhen probably damaging (0.994); catalogued as rs201729927, COSV58182857; called by muse, mutect2, varscan2
- LIPG | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs536799767, COSV54296081; called by muse, mutect2, varscan2
- MYH4 | c.5137G>A p.A1713T | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as COSV55124114; called by muse, mutect2, varscan2
- NAPG | c.496C>G p.R166G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV59796209, COSV59798076; called by muse, mutect2, varscan2
- OR13H1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV58548293; called by muse, mutect2, varscan2
- ORMDL1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV57877419; called by muse, mutect2, varscan2
- PPP3CA | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59929464; called by muse, mutect2, varscan2
- SIAE | c.199A>C p.T67P | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55015646; called by muse, mutect2, varscan2
- SLC8A1 | c.2374G>T p.V792F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60493063, COSV60493563; called by muse, mutect2, varscan2
- SLITRK1 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as COSV65675304; called by muse, mutect2, varscan2
- SLITRK4 | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV62022486, COSV62023994, COSV62025718; called by muse, mutect2, varscan2
- SYNPO | c.2399G>A p.R800H (on ENST00000394243 / NM_001166208.2; = p.R556H on NM_007286.6) | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs769984982, COSV56942284; called by muse, mutect2, varscan2
- TIAM1 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs371730791; called by muse, mutect2, varscan2
- TMPRSS7 | c.1692T>A p.F564L (on ENST00000452346; = p.F438L on NM_001042575.2) | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV101340092, COSV69982247; called by muse, mutect2
- TRIM42 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53885989; called by muse, mutect2
- TTN | c.91223G>A p.S30408N (on ENST00000591111; = p.S22984N on NM_003319.4) | Missense Mutation (SNP) | VAF 28/178 reads (16%) | PolyPhen benign (0); catalogued as COSV60273674; called by muse, mutect2, varscan2
- ZNF208 | c.2800A>G p.K934E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68111308; called by muse, mutect2
- ZNF292 | c.6343C>T p.R2115* | Nonsense Mutation (SNP) | VAF 32/103 reads (31%) | catalogued as rs866467799, COSV60535418; called by muse, mutect2, varscan2
- ZNF317 | c.1244A>G p.K415R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs765623451, COSV56111198; called by muse, mutect2, varscan2
- HEATR5B | c.105dup p.V36Sfs*19 | Frame Shift Ins (INS) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- XYLT1 | c.2169dup p.V724Sfs*10 | Frame Shift Ins (INS) | VAF 20/183 reads (11%) | called by mutect2, pindel, varscan2
- YLPM1 | c.3763_3769del p.S1255Mfs*115 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- OR6S1 | c.546C>T p.C182= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs376650163; called by muse, mutect2, varscan2
- RPTOR | c.1626C>T p.I542= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs750153454, COSV60815737; called by muse, mutect2, varscan2
- TLX1NB | n.1343C>T | RNA (SNP) | VAF 9/21 reads (43%) | catalogued as rs1416693290; called by muse, mutect2, varscan2
